CCDI case PBBVZL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/67c2c454-a361-465d-b44c-08bf9d574f2b

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9473/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 7.6 years (2,793 days).

Biospecimens (3 samples)
- Sample 0DIPKR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIPL1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DIPLR: Tissue type: Tumor; Specimen type: Solid Tissue.
